Somatic mutation profile of tumor specimen 0DPMS4 from CCDI case PBCDVA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoid tumor of uncertain malignant potential; Tissue or organ of origin: Appendix; Age at diagnosis: 13.9 years (5,068 days).
Specimen 0DPMS4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2933984-e0b9-4306-a4e7-87a0c8a0e535.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPMQT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6ae6fc9-165a-40c3-9da1-eb7b3e7b07c8

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 15/377 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
